Somatic mutation profile of tumor specimen 0DL1TM from CCDI case PBBWVY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tumor cells, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.7 years (4,290 days).
Specimen 0DL1TM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31bdcb2e-88f1-4f9d-8931-31c40d9e8c3a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DL1SX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44d1148d-38ee-4573-a949-9d437b4d9e2a

The open-access MAF lists 35 somatic variants for this specimen: 26 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 4, Intron 2, 3'UTR 2, Frame Shift Ins 2, Nonsense Mutation 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CASKIN1 | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 77/756 reads (10%) | catalogued as COSV58872413; called by muse, mutect2, varscan2
- FABP2 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 269/609 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762974442, COSV99917024; called by muse, mutect2, varscan2
- GDPD5 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 158/595 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369743472; called by muse, mutect2, varscan2
- HMGCLL1 | c.875C>T p.T292M | Missense Mutation (SNP) | VAF 134/568 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.072); catalogued as rs201456410, COSV51449306; called by muse, mutect2, varscan2
- LMLN | c.158C>G p.S53C | Missense Mutation (SNP) | VAF 327/592 reads (55%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.112); catalogued as COSV54563511, COSV99502448; called by muse, mutect2, varscan2
- OR5K2 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 237/800 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs771022097, COSV71143450; called by muse, mutect2, varscan2
- UNC79 | c.1411C>T p.R471W (on ENST00000393151 / NM_001346218.2; = p.R294W on NM_020818.5) | Missense Mutation (SNP) | VAF 89/855 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56418190; called by muse, mutect2, varscan2
- AATK | c.3622C>G p.R1208G (on ENST00000326724 / NM_001080395.3; = p.R1105G on NM_004920.2) | Missense Mutation (SNP) | VAF 99/389 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AKAP13 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 22/519 reads (4%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.355); called by muse, mutect2
- ALDOA | c.837A>C p.E279D (on ENST00000642816 / NM_001243177.4; = p.E225D on NM_184041.5) | Missense Mutation (SNP) | VAF 245/556 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 47/1441 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CCDC138 | c.561A>G p.I187M | Missense Mutation (SNP) | VAF 26/848 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- DIP2A | c.1800A>T p.K600N | Missense Mutation (SNP) | VAF 133/588 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GABRA4 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 125/340 reads (37%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 50/1444 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- HOOK2 | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 566/1364 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- JAKMIP1 | c.2462dup p.L821Ffs*? | Frame Shift Ins (INS) | VAF 264/719 reads (37%) | called by mutect2, varscan2
- KIF4A | c.2354dup p.E786Gfs*9 | Frame Shift Ins (INS) | VAF 300/710 reads (42%) | called by mutect2, varscan2
- L3MBTL4 | c.1136G>A p.C379Y | Missense Mutation (SNP) | VAF 278/665 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP4R3A | c.521T>A p.L174Q | Missense Mutation (SNP) | VAF 52/1338 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RAPGEF2 | c.147T>A p.S49R | Missense Mutation (SNP) | VAF 22/814 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- SELL | c.1148A>G p.D383G (on ENST00000650983; = p.D370G on NM_000655.5) | Missense Mutation (SNP) | VAF 100/892 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TP53BP1 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 74/986 reads (8%) | called by muse, mutect2
- TUBB6 | c.1211A>G p.D404G | Missense Mutation (SNP) | VAF 187/436 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- USH2A | c.12872C>T p.S4291F | Missense Mutation (SNP) | VAF 146/602 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- XYLT1 | c.1321C>G p.R441G | Missense Mutation (SNP) | VAF 246/614 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- AKAP12 | c.2616C>G p.P872= | Silent (SNP) | VAF 340/411 reads (83%) | called by muse, mutect2, varscan2
- LRRC20 | c.489C>T p.I163= (on ENST00000355790 / NM_207119.3; = p.I107= on NM_018205.4) | Silent (SNP) | VAF 56/758 reads (7%) | catalogued as rs1008889908, COSV62938968; called by muse, mutect2
- SLC12A7 | c.2145G>A p.T715= | Silent (SNP) | VAF 207/384 reads (54%) | catalogued as rs769411204, COSV99369500; called by muse, mutect2, varscan2
- SPAG4 | c.624C>T p.R208= | Silent (SNP) | VAF 19/453 reads (4%) | called by muse, mutect2
- ASB1 | c.*62G>A | 3'UTR (SNP) | VAF 57/179 reads (32%) | catalogued as rs1228223623; called by muse, mutect2, varscan2
- CFAP65 | c.-2-93C>G | Intron (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 4/43 reads (9%) | called by mutect2, varscan2
- SHROOM4 | c.*9G>A | 3'UTR (SNP) | VAF 263/702 reads (37%) | called by muse, mutect2, varscan2
- SMARCD3 | c.-10C>T | 5'UTR (SNP) | VAF 111/264 reads (42%) | catalogued as rs765799403; called by muse, mutect2, varscan2
